Somatic mutation profile of tumor specimen C3L-00277-03 (aliquot CPT0011520006) from CPTAC case C3L-00277, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 69.9 years (25,515 days).
Specimen C3L-00277-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 71de07ce-b93d-4578-b87a-ef8d1b74f689.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00277-31 (Blood Derived Normal), aliquot CPT0012450002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/afc341ff-99cf-4cc8-9365-129d6fd1192a

The open-access MAF lists 36 somatic variants for this specimen: 23 protein-altering or splice-affecting, 11 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 11, Nonsense Mutation 2, Intron 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 78/204 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAMTS18 | c.1198G>A p.E400K | Missense Mutation (SNP) | VAF 44/320 reads (14%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.557); catalogued as rs1239818884; called by muse, mutect2, varscan2
- ARHGEF2 | c.2482C>T p.R828W (on ENST00000361247 / NM_001162383.2; = p.R800W on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/243 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs1366836897; called by muse, mutect2
- CACNG3 | c.412G>A p.A138T | Missense Mutation (SNP) | VAF 27/134 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.558); catalogued as COSV50064715; called by muse, mutect2, varscan2
- CYP26B1 | c.1069G>A p.V357I | Missense Mutation (SNP) | VAF 71/376 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.972); catalogued as rs541205721, COSV50014098; called by muse, mutect2, varscan2
- FGD1 | c.394C>T p.R132W | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs746549256, COSV100911078; called by muse, mutect2, varscan2
- HHIPL2 | c.1579C>T p.R527* | Nonsense Mutation (SNP) | VAF 9/77 reads (12%) | catalogued as rs779253171, COSV58563608, COSV58567693; called by muse, mutect2, varscan2
- SBDS | c.722A>T p.D241V | Missense Mutation (SNP) | VAF 119/324 reads (37%) | SIFT tolerated (0.41); PolyPhen benign (0.024); catalogued as COSV55888438; called by muse, mutect2, varscan2
- SOX17 | c.323C>T p.A108V | Missense Mutation (SNP) | VAF 59/152 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs931390946, COSV52024391; called by muse, mutect2, varscan2
- TNFAIP2 | c.1840G>A p.A614T | Missense Mutation (SNP) | VAF 95/336 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as rs368740303; called by muse, mutect2, varscan2
- VCAM1 | c.1740A>C p.E580D | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.398); catalogued as rs1232982471; called by muse, mutect2, varscan2
- C2orf73 | c.268G>A p.A90T | Missense Mutation (SNP) | VAF 30/172 reads (17%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- DOCK4 | c.5101C>A p.P1701T | Missense Mutation (SNP) | VAF 34/269 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ESF1 | c.1430A>G p.D477G | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- IL1RL2 | c.1724G>C p.G575A | Missense Mutation (SNP) | VAF 28/141 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MUC16 | c.20261A>G p.D6754G | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- NTRK1 | c.307C>T p.L103F | Missense Mutation (SNP) | VAF 158/347 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- NYAP2 | c.1883C>T p.P628L | Missense Mutation (SNP) | VAF 47/263 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OR8B3 | c.784T>C p.Y262H | Missense Mutation (SNP) | VAF 46/178 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- PEX19 | c.559G>T p.V187L | Missense Mutation (SNP) | VAF 61/486 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- SMAD4 | c.983_985del p.Y328del | In Frame Del (DEL) | VAF 65/195 reads (33%) | called by mutect2, pindel, varscan2
- SPEN | c.3455C>A p.S1152* | Nonsense Mutation (SNP) | VAF 19/73 reads (26%) | called by muse, mutect2, varscan2
- ULK2 | c.1235G>T p.R412L | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2
- B3GNT5 | c.207G>A p.A69= | Silent (SNP) | VAF 75/202 reads (37%) | catalogued as rs201133824; called by muse, mutect2, varscan2
- CCDC88C | c.15C>G p.V5= | Silent (SNP) | VAF 58/201 reads (29%) | catalogued as rs1174385287; called by muse, mutect2, varscan2
- CUL9 | c.1620C>T p.S540= | Silent (SNP) | VAF 39/124 reads (31%) | catalogued as rs369198783; called by mutect2, varscan2
- GABRA5 | c.648G>A p.A216= | Silent (SNP) | VAF 54/186 reads (29%) | catalogued as rs778210544, COSV59476246; called by muse, mutect2, varscan2
- IDO2 | c.708C>T p.I236= (on ENST00000389060; = p.I249= on NM_194294.2) | Silent (SNP) | VAF 24/82 reads (29%) | called by muse, mutect2, varscan2
- MED16 | c.1086G>A p.S362= | Silent (SNP) | VAF 28/140 reads (20%) | catalogued as rs757826255, COSV54125914; called by muse, mutect2, varscan2
- MYH13 | c.5661G>A p.E1887= | Silent (SNP) | VAF 38/129 reads (29%) | catalogued as COSV99354622; called by muse, mutect2, varscan2
- OAZ3 | c.96C>T p.Y32= | Silent (SNP) | VAF 63/444 reads (14%) | catalogued as rs755800995; called by muse, mutect2, varscan2
- PI4KA | c.2637C>T p.S879= | Silent (SNP) | VAF 9/92 reads (10%) | catalogued as rs757543742; called by muse, mutect2, varscan2
- TMEM8B | c.1248C>T p.L416= | Silent (SNP) | VAF 34/151 reads (23%) | catalogued as rs1030771341; called by muse, mutect2, varscan2
- TXNDC15 | c.462G>A p.A154= | Silent (SNP) | VAF 23/223 reads (10%) | catalogued as rs143292161, COSV100613640; called by muse, mutect2, varscan2
- CTSK | c.-1-536G>A | Intron (SNP) | VAF 29/332 reads (9%) | called by muse, mutect2
- FSTL4 | c.127-16120G>A | Intron (SNP) | VAF 15/84 reads (18%) | catalogued as rs542386260; called by muse, mutect2, varscan2
